Somatic mutation profile of tumor specimen TCGA-PR-A5PF-01A (aliquot TCGA-PR-A5PF-01A-11D-A35D-08) from TCGA case TCGA-PR-A5PF, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 62.9 years (22,987 days).
Specimen TCGA-PR-A5PF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b5a46ed-0fca-4e43-9432-e293fd23498b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PR-A5PF-10A (Blood Derived Normal), aliquot TCGA-PR-A5PF-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1cfada3-be3f-4058-9c3a-35a5b520342d

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 12, Silent 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2B | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as rs374276624; called by muse, mutect2, varscan2
- EYS | c.305A>T p.N102I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs1274819145, COSV100676410, COSV60980288; called by muse, mutect2, varscan2
- KRT72 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs145882334; called by muse, mutect2, varscan2
- STON1 | c.1243A>G p.I415V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV100562349; called by muse, mutect2, varscan2
- TBC1D10B | c.1868A>G p.E623G | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1421431926; called by muse, mutect2, varscan2
- ADAMTS10 | c.1874T>A p.F625Y | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BDH1 | c.49del p.T17Pfs*2 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- BICDL2 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); called by muse, mutect2
- CYRIA | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- MINK1 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- RUFY3 | c.611A>G p.E204G | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBGCP6 | c.4672C>A p.L1558M | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZBTB47 | c.1577A>G p.E526G | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.074); called by muse, mutect2
- B4GALNT4 | c.918G>C p.G306= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1405132959, COSV57321344; called by muse, mutect2, varscan2
- EMC9 | c.46C>T p.L16= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- INSRR | c.1806T>A p.P602= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- MAP3K19 | c.3966C>G p.S1322= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV64326979; called by mutect2, varscan2
- PPP1R14D | c.48G>T p.G16= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1446519507; called by muse, mutect2, varscan2
- ZFP41 | c.573A>G p.K191= | Silent (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- ZNF80 | c.570G>A p.K190= | Silent (SNP) | VAF 50/127 reads (39%) | called by muse, mutect2, varscan2
